Gene-level copy-number profile of tumor specimen TCGA-18-3417-01A from TCGA case TCGA-18-3417, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.8 years (24,019 days).
Specimen TCGA-18-3417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0cef2908-3fee-48e6-bfb0-5297f2f350e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3417-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/da1e2853-ae9b-486c-9197-fb377c971883

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 836; copy number 2: 15,994; copy number 3: 12,190; copy number 4: 11,811; copy number 5: 3,404; copy number 6: 8,173; copy number 7: 4,463; copy number 8: 328; copy number 9: 219; copy number 10: 636; copy number 12: 826; copy number 13: 170; copy number 14: 110; copy number 15: 290; copy number 16: 27; copy number 17: 54; copy number 18: 10; copy number 21: 24; copy number 25: 5; copy number 27: 65; copy number 28: 1; copy number 29: 13; copy number 32: 9; copy number 34: 38; copy number 40: 98; copy number 41: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3417-01A-01D-1439-01): tumor purity 0.31, ploidy 3.69, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18,931 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,603 genes, copy number 5–41 (broad region; genes not listed).
- chr2:38,814–96,986,580, 1,744 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:172,735,274–215,713,895, 678 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:35,638,945–43,106,079, 171 genes, copy number 6–7 (broad region; genes not listed).
- chr3:51,385,291–53,347,586, 93 genes, copy number 6 (broad region; genes not listed).
- chr3:53,333,060–53,387,836, 2 genes, copy number 6: SNORD38C, AC112218.1.
- chr3:54,918,231–56,683,237, 17 genes, copy number 6–10 (within-gene range 2–10): LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133, CCDC66, TASOR.
- chr3:58,008,400–59,050,084, 23 genes, copy number 6 (within-gene range 2–6): FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1.
- chr3:61,561,569–62,875,416, 12 genes, copy number 5–7: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7–15 (broad region; genes not listed).
- chr4:46,918,900–49,246,915, 41 genes, copy number 6: GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr5:58,198–55,173,177, 787 genes, copy number 7–14 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 6 (broad region; genes not listed).
- chr8:50,490,795–51,809,445, 8 genes, copy number 5 (within-gene range 3–5): AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1.
- chr8:66,363,774–145,066,685, 1,238 genes, copy number 6–9 (broad region; genes not listed).
- chr9:32,293,558–37,592,604, 223 genes, copy number 8 (broad region; genes not listed).
- chr10:44,712–53,766,614, 937 genes, copy number 5–6 (broad region; genes not listed).
- chr10:59,788,747–61,026,420, 12 genes, copy number 5: CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr10:69,994,276–71,815,947, 31 genes, copy number 5–6 (within-gene range 3–6): LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622, UNC5B, UNC5B-AS1, SLC29A3, AL359183.1, CDH23, CDH23-AS1.
- chr12:66,767–34,249,958, 850 genes, copy number 12–21 (broad region; genes not listed).
- chr16:11,555–1,884,294, 160 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:48,026,167–83,095,122, 1,096 genes, copy number 5 (broad region; genes not listed).
- chr18:5,002,759–6,463,015, 29 genes, copy number 5: PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27.
- chr18:11,326,270–12,991,173, 68 genes, copy number 5–8 (broad region; genes not listed).
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 6–8 (broad region; genes not listed).
- chr21:10,328,411–20,828,622, 148 genes, copy number 5–28 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
